CCDI case PBCMXW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ee59b5dc-1fea-4480-86e3-093a49bdd235

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Craniopharyngioma, adamantinomatous: ICD-O-3 morphology code: 9351/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.6 years (1,685 days).

Biospecimens (3 samples)
- Sample 0DVPN5: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVPOM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DVPP7: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
